Somatic mutation profile of tumor specimen TCGA-DX-A7ES-01A (aliquot TCGA-DX-A7ES-01A-31D-A38Z-09) from TCGA case TCGA-DX-A7ES, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 50.7 years (18,528 days).
Specimen TCGA-DX-A7ES-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91c6ea3b-685f-437d-b3c6-5f2356cbee6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A7ES-10A (Blood Derived Normal), aliquot TCGA-DX-A7ES-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c5e52ed-0a05-4269-aaaa-5d6eaf8ea4b5

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 17, Silent 5, Nonsense Mutation 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANGEL1 | c.441G>A p.W147* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV99200448; called by muse, mutect2, varscan2
- APOA5 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as rs781109287, COSV99911196, COSV99911379; called by muse, mutect2, varscan2
- CPM | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 112/459 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.066); catalogued as COSV100615199, COSV58032601; called by muse, mutect2, varscan2
- DOCK11 | c.3091C>A p.L1031M | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV99354324; called by muse, mutect2, varscan2
- DYNC1I2 | c.1739A>G p.H580R | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.017); catalogued as COSV99784132; called by muse, mutect2, varscan2
- EIF4A2 | c.795T>G p.C265W | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99961287; called by muse, mutect2, varscan2
- GNAS | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); catalogued as COSV58328582; called by muse, mutect2
- GREB1 | c.5797G>T p.A1933S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52191764, COSV99303391; called by muse, mutect2
- HNRNPM | c.1618G>A p.G540S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV99725754; called by muse, mutect2, varscan2
- HNRNPM | c.1808G>A p.G603D | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV99725757; called by muse, varscan2
- HYDIN | c.701A>T p.H234L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.223); catalogued as COSV99864128; called by muse, mutect2, varscan2
- MVP | c.1219A>G p.M407V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100651658; called by muse, mutect2, varscan2
- NUP107 | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as COSV99971924; called by muse, mutect2, varscan2
- PABPC4 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as rs567524034, COSV100790901; called by muse, mutect2, varscan2
- PSMD1 | c.823A>G p.I275V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as rs1324249833, COSV100433766; called by muse, mutect2, varscan2
- PSRC1 | c.736C>T p.P246S (on ENST00000409138 / NM_001363309.1; = p.P216S on NM_032636.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.012); catalogued as COSV100883530; called by muse, mutect2, varscan2
- RNF111 | c.41T>G p.L14* | Nonsense Mutation (SNP) | VAF 3/30 reads (10%) | catalogued as COSV100789116; called by muse, mutect2
- SATB1 | c.1990C>T p.Q664* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV100113345, COSV58673722; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 17/70 reads (24%) | PolyPhen benign (0.235); catalogued as rs771372770, COSV59570338; called by muse, mutect2, varscan2
- TRO | c.3617A>G p.N1206S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.063); catalogued as rs1569546469, COSV99436954; called by muse, mutect2, varscan2
- ZNF263 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV99527067; called by muse, mutect2
- GPKOW | c.868_886del p.R290Sfs*86 | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | called by mutect2, pindel, varscan2
- CCAR1 | c.2427T>C p.D809= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV99771240; called by muse, mutect2, varscan2
- GLIPR1L1 | c.402C>G p.V134= | Silent (SNP) | VAF 156/243 reads (64%) | catalogued as COSV100158024; called by muse, mutect2, varscan2
- HNRNPM | c.1743G>A p.L581= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs895521937, COSV99725755; called by muse, varscan2
- KDM2A | c.1866C>T p.L622= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs749894685, COSV100445745; called by muse, mutect2, varscan2
- MAB21L3 | c.1083G>A p.P361= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as rs540660033, COSV101046338; called by muse, mutect2, varscan2
